Somatic mutation profile of tumor specimen TCGA-16-0861-01A (aliquot TCGA-16-0861-01A-01D-1492-08) from TCGA case TCGA-16-0861, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.1 years (23,778 days).
Specimen TCGA-16-0861-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bff1c316-b080-4ee6-bafb-95d3e6a51e8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-16-0861-10A (Blood Derived Normal), aliquot TCGA-16-0861-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ba7d3a9-8984-4c85-8d76-a6ded3a78223

The open-access MAF lists 63 somatic variants for this specimen: 46 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 15, Nonsense Mutation 4, Splice Site 2, RNA 1, Intron 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.209+4_209+7del p.X70_splice | Splice Site (DEL) | VAF 13/22 reads (59%) | hotspot (GDC flag); catalogued as rs398123318; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ARHGAP28 | c.1905+2T>C p.X635_splice (on ENST00000383472 / NM_001366230.1; = p.X476_splice on NM_001010000.3) | Splice Site (SNP) | VAF 55/122 reads (45%) | catalogued as COSV51630838; called by muse, mutect2, varscan2
- ATP6V1A | c.439A>G p.I147V | Missense Mutation (SNP) | VAF 6/151 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56360806; called by muse, mutect2
- AVPR1A | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 125/293 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs1321821927, COSV54545511; called by muse, mutect2, varscan2
- BIRC6 | c.13007G>A p.S4336N | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.258); catalogued as COSV70195106; called by muse, mutect2, varscan2
- BTRC | c.421T>G p.F141V (on ENST00000370187 / NM_033637.4; = p.F105V on NM_003939.5) | Missense Mutation (SNP) | VAF 59/69 reads (86%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as COSV64560326; called by muse, mutect2, varscan2
- CIDEA | c.458A>T p.E153V | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57597126; called by muse, mutect2, varscan2
- CMYA5 | c.5680T>G p.W1894G | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as COSV71404027; called by muse, mutect2
- DNAH5 | c.6332G>A p.R2111H | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs946204829, COSV54202034; called by muse, mutect2, varscan2
- DNAJC6 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 127/303 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54769123; called by muse, mutect2, varscan2
- EHD3 | c.400A>T p.N134Y | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59029095; called by muse, mutect2, varscan2
- EMSY | c.228A>C p.L76F | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58257018; called by muse, mutect2, varscan2
- F9 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 73/95 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM057674, CM057675, CM125298, COSV54378486; called by muse, mutect2, varscan2
- FGA | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1283170104, COSV57392420; called by muse, mutect2, varscan2
- FLG | c.2410G>T p.E804* | Nonsense Mutation (SNP) | VAF 216/526 reads (41%) | catalogued as COSV64235891; called by muse, mutect2, varscan2
- FRYL | c.2851C>G p.L951V | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51938400; called by muse, mutect2, varscan2
- GSS | c.1360A>T p.I454F | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.29); catalogued as COSV53622357; called by muse, varscan2
- GUCY2D | c.1340C>G p.P447R | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV54694268; called by muse, mutect2, varscan2
- GZMB | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 104/164 reads (63%) | catalogued as rs199605460, COSV53539818; called by muse, mutect2, varscan2
- HS3ST3A1 | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1344458516, COSV52372499; called by muse, mutect2, varscan2
- IARS1 | c.2900C>T p.A967V | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV65112901; called by muse, mutect2, varscan2
- IARS1 | c.2899G>T p.A967S | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100986734; called by muse, mutect2, varscan2
- INSR | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV57157020; called by muse, mutect2, varscan2
- IQUB | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 124/305 reads (41%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs371332386; called by muse, mutect2, varscan2
- ME1 | c.490T>A p.C164S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV63837411; called by muse, mutect2, varscan2
- MRC2 | c.2293G>A p.V765I | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV57636284; called by muse, mutect2, varscan2
- N4BP3 | c.1498G>A p.V500M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376298616, COSV51061670; called by muse, mutect2, varscan2
- NCAPH2 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55366096; called by muse, mutect2, varscan2
- NIN | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1442191019, COSV55379342; called by muse, mutect2, varscan2
- NPAP1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs780506627, COSV61503994; called by muse, mutect2, varscan2
- PCDHB15 | c.456T>G p.F152L | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.168); catalogued as COSV50858111; called by muse, mutect2, varscan2
- PDS5B | c.2812G>C p.E938Q | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.768); catalogued as COSV59722886; called by muse, mutect2, varscan2
- PITX3 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV64174073; called by muse, mutect2, varscan2
- RAB11B | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs754522300, COSV60085170; called by muse, mutect2, varscan2
- RASGEF1C | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV63177103; called by muse, mutect2, varscan2
- RERG | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 68/104 reads (65%) | catalogued as COSV56999753; called by muse, mutect2, varscan2
- SAMD9 | c.2720G>T p.G907V | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV66072765; called by muse, mutect2, varscan2
- SUSD1 | c.1349C>A p.T450K | Missense Mutation (SNP) | VAF 83/193 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62582070; called by muse, mutect2, varscan2
- SYT1 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 79/195 reads (41%) | catalogued as COSV54031457; called by muse, mutect2, varscan2
- TTN | c.63467C>T p.P21156L (on ENST00000591111; = p.P13732L on NM_003319.4) | Missense Mutation (SNP) | VAF 76/194 reads (39%) | PolyPhen probably damaging (0.917); catalogued as rs1371471381, COSV100597244, COSV59869160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VAV3 | c.304G>T p.V102F | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64064684; called by muse, mutect2, varscan2
- WNK1 | c.5441C>T p.A1814V (on ENST00000315939 / NM_018979.4; = p.A1567V on NM_014823.3) | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs953160606, COSV60024998; called by muse, mutect2
- ZNF527 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1276546322, COSV62229340; called by muse, mutect2, varscan2
- ZNF608 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1008720444, COSV60434966; called by muse, mutect2, varscan2
- CCDC15 | c.1153_1156delinsG p.K385_T386delinsA | In Frame Del (DEL) | VAF 57/211 reads (27%) | called by pindel, varscan2*
- HEATR5A | c.1488_1504del p.G497* | Frame Shift Del (DEL) | VAF 76/131 reads (58%) | called by mutect2, pindel, varscan2
- ATP11C | c.1830T>C p.D610= | Silent (SNP) | VAF 58/93 reads (62%) | catalogued as COSV59559069; called by muse, mutect2, varscan2
- ATXN2L | c.1830A>T p.P610= | Silent (SNP) | VAF 60/162 reads (37%) | catalogued as COSV57364766; called by muse, mutect2, varscan2
- DLEC1 | c.2457T>C p.F819= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as COSV57294676; called by muse, mutect2, varscan2
- DRC7 | c.1035G>A p.K345= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV61052805; called by muse, mutect2, varscan2
- DSC1 | c.462C>T p.H154= | Silent (SNP) | VAF 52/120 reads (43%) | catalogued as rs1196619139, COSV57141302; called by muse, mutect2, varscan2
- DST | c.20631C>T p.G6877= (on ENST00000361203 / NM_001374722.1; = p.G4574= on NM_015548.5) | Silent (SNP) | VAF 78/200 reads (39%) | catalogued as rs760689511, COSV54995946; called by muse, mutect2, varscan2
- ELMOD1 | c.447T>A p.T149= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV56190340, COSV56190396; called by muse, mutect2, varscan2
- HIPK2 | c.93G>A p.L31= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs931528143, COSV61225292; called by muse, mutect2, varscan2
- KSR2 | c.831G>A p.P277= | Silent (SNP) | VAF 150/362 reads (41%) | catalogued as rs752651619, COSV60365054; called by muse, mutect2, varscan2
- LY75 | c.2076T>C p.D692= | Silent (SNP) | VAF 109/234 reads (47%) | catalogued as COSV55101574; called by muse, mutect2, varscan2
- PPP4R3A | c.687T>C p.A229= | Silent (SNP) | VAF 83/110 reads (75%) | catalogued as COSV61503361; called by muse, mutect2, varscan2
- PTPRN | c.2616C>T p.F872= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV55345341; called by muse, mutect2, varscan2
- SV2B | c.1308C>T p.Y436= | Silent (SNP) | VAF 96/205 reads (47%) | catalogued as rs140230861; called by muse, mutect2, varscan2
- TUBA3D | c.540C>T p.A180= | Silent (SNP) | VAF 119/467 reads (25%) | catalogued as rs544741714, COSV58310648; called by muse, mutect2, varscan2
- ZFR2 | c.1173G>A p.A391= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs963844831, COSV53596101; called by muse, mutect2
- IGKV1-13 | n.217T>A | RNA (SNP) | VAF 76/185 reads (41%) | called by mutect2, varscan2
- SV2C | c.581-20769G>A | Intron (SNP) | VAF 67/168 reads (40%) | catalogued as rs878875446, COSV59213582; called by muse, mutect2, varscan2
